Gene-level copy-number profile of tumor specimen TCGA-E1-A7YQ-01A from TCGA case TCGA-E1-A7YQ, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Oligodendroglioma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 58.4 years (21,341 days).
Specimen TCGA-E1-A7YQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LGG.57417012-cde0-4ebc-9ac8-e6268208cda0.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-E1-A7YQ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c4dc4863-82be-4cc7-926f-8e8c2a110e0c

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 2,329; copy number 2: 89; copy number 3: 19,613; copy number 4: 16,022; copy number 5: 10,288; copy number 6: 8,020; copy number 7: 3,040; copy number 23: 39; copy number 24: 4; copy number 25: 306; copy number 26: 8; copy number 38: 24; copy number 39: 37.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-E1-A7YQ-01A-11D-A34I-01): tumor purity 0.59, ploidy 2.89, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 3,458 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–232,223,145, 2,220 genes, copy number 7 (broad region; genes not listed).
- chr1:232,700,204–248,919,946, 383 genes, copy number 7 (broad region; genes not listed).
- chr5:58,198–28,809,291, 433 genes, copy number 7 (broad region; genes not listed).
- chr5:28,897,785–28,927,459, 4 genes, copy number 7: AC010385.2, LSP1P3, AC010385.1, AC010385.3.
- chr7:27,269,357–37,586,329, 184 genes, copy number 25–39 (broad region; genes not listed).
- chr7:41,667,168–42,264,100, 4 genes, copy number 24: INHBA, INHBA-AS1, GLI3, HMGN2P30.
- chr7:46,144,937–52,897,807, 71 genes, copy number 23–38 (broad region; genes not listed).
- chr7:53,862,233–57,837,046, 159 genes, copy number 25 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,329. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
